Surgical pathology report (de-identified scan), TCGA case TCGA-CV-6938, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-CV-6938-01A (Primary Tumor).

[page 1 of 2]
SUPPLEMENTAL REPORT

COMMENT: Examination of decalcified bone from the specimens designated bone from left nasal intima, left infraorbital nerve, tumor from pterygoid, infraorbital tissue, pterygoid plate and tissue from pterygoid (specimens A, C, E, F, G, and I, respectively) shows invasion into the bone by well differentiated squamous carcinoma. The squamous carcinoma is close to but does not invade into the bone in the tissue from superior nasal cavity (specimen B). No invasion into the bone is seen in the hemimandibulectomy specimen (specimen L).

DIAGNOSIS

- (A) BONE FROM LEFT NASAL INTIMA:
INVASIVE SQUAMOUS CARCINOMA, WELL DIFFERENTIATED. (SEE COMMENT)
- (B) TISSUE FROM SUPERIOR NASAL CAVITY:
INVASIVE SQUAMOUS CARCINOMA, WELL DIFFERENTIATED. (SEE COMMENT)
- (C) LEFT INFRAORBITAL NERVE:
INVASIVE SQUAMOUS CARCINOMA, WELL DIFFERENTIATED IN PERINEURAL SPACE.
- (D) REMAINDER OF MANDIBLE:
Grossly unremarkable bone (gross identification only).
- (E) TUMOR FROM PTERYGOID:
INVASIVE SQUAMOUS CARCINOMA, WELL DIFFERENTIATED. (SEE COMMENT)
TUMOR LESS THAN 0.1 MM FROM SURGICAL MARGIN.
- (F) INFRAORBITAL TISSUE:
Sinonasal mucosa in connective tissue with focal granulation tissue and fibrosis, no tumor present. (See Comment)
- (G) PTERYGOID PLATE:
Sections pending decalcification. (See Comment)
- (H) INFERIOR TURBINATE:
Sinonasal tissue consistent with turbinate, no tumor present.
- (I) TISSUE FROM PTERYGOID:
INVASIVE SQUAMOUS CARCINOMA, WELL DIFFERENTIATED. (SEE COMMENT)
- (J) SOFT PALATE:
INVASIVE SQUAMOUS CARCINOMA, WELL DIFFERENTIATED.
Margins of resection free of tumor.
- (K) TISSUE LATERAL WALL NASOPHARYNX:
INVASIVE SQUAMOUS CARCINOMA, WELL DIFFERENTIATED.
- (L) HEMIMANDIBULECTOMY:

[page 2 of 2]
INVASIVE SQUAMOUS CARCINOMA, WELL DIFFERENTIATED.
TUMOR WITHIN 0.1 MM OF SUPERIOR, POSTERIOR SOFT TISSUE MARGIN,
ALL OTHER SURGICAL MARGINS FREE OF TUMOR. (SEE COMMENT)

COMMENT

Bone from specimens A, B, C, D, E, F, G, I and L will be submitted pending decalcification. A supplemental report assessing bone invasion will be issued at a later time.

SPECIMEN

- (A) BONE FROM LEFT NASAL INTIMA:
- (B) TISSUE FROM SUPERIOR NASAL CAVITY:
- (C) LEFT INFRAORBITAL NERVE:
- (D) REMAINDER OF MANDIBLE:
- (E) TUMOR FROM PTERYGOID:
- (F) INFRAORBITAL TISSUE:
- (G) PTERYGOID PLATE:
- (H) INFERIOR TURBINATE:
- (I) TISSUE FROM PTERYGOID:
- (J) SOFT PALATE:
- (K) TISSUE LATERAL WALL NASOPHARYNX:
- (L) HEMIMANDIBULECTOMY:

Source: NCI Genomic Data Commons file 21ae437e-fb15-4963-b1b0-4f273cb0f740 (TCGA-CV-6938.756E48C6-3AA8-486C-A3A8-0BAD41AEBB9C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).